Somatic mutation profile of tumor specimen MBCProject_4683_T1_WES (aliquot MBCProject_4683_T1_WES_1) from CMI case MBCProject_4683, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 42.7 years (15,594 days).
Specimen MBCProject_4683_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebb3222a-58de-4585-b1b0-9497cf7834da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4683_SALIVA (Saliva), aliquot MBCProject_4683_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e89aeab4-414e-4164-9a86-10c4d54c0e4c

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Splice Site 3, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DEF8 | c.518G>A p.R173Q (on ENST00000268676 / NM_207514.3; = p.R112Q on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs753437162; called by muse, mutect2
- FLNB | c.6034C>G p.L2012V | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55882220; called by muse, mutect2, varscan2
- HSD11B2 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121917780, CM950650; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MGAM2 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762345051, COSV101522880; called by muse, mutect2, varscan2
- PCDHA11 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV56516881; called by muse, mutect2, varscan2
- PHF1 | c.1088G>A p.R363H (on ENST00000374516 / NM_024165.3; = p.T359= on NM_002636.5) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.964); catalogued as rs1045270321; called by muse, mutect2, varscan2
- PIP5KL1 | c.1067G>T p.R356L (on ENST00000388747 / NM_001135219.2; = p.R153L on NM_173492.1) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV55945809; called by muse, mutect2, varscan2
- SIN3B | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs200695908; called by muse, mutect2, varscan2
- UBE2D2 | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.099); catalogued as COSV54079119; called by muse, mutect2, varscan2
- UTRN | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as rs150084858, COSV100839954; called by muse, mutect2, varscan2
- CAD | c.2287+1G>T p.X763_splice | Splice Site (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- CAD | c.2287+2T>G p.X763_splice | Splice Site (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- CFAP47 | c.5444A>T p.Y1815F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- FLT4 | c.2981G>A p.R994Q | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- GREB1 | c.2299C>G p.L767V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITGB1BP2 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.781); called by muse, varscan2
- PKDREJ | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN11A | c.959+1G>T p.X320_splice | Splice Site (SNP) | VAF 32/137 reads (23%) | called by muse, mutect2, varscan2
- SHISA9 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TET2 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 48/322 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TIAM1 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CD248 | c.1368G>A p.T456= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs147196655; called by muse, mutect2, varscan2
- MUC12 | c.3468C>G p.A1156= (on ENST00000379442; = p.A1013= on NM_001164462.1) | Silent (SNP) | VAF 120/678 reads (18%) | called by muse, mutect2, varscan2
- WDR61 | c.492C>T p.A164= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs1432744338; called by muse, mutect2, varscan2
- ZNF28 | c.360T>G p.T120= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- CD99L2 | c.130+1794A>G | Intron (SNP) | VAF 42/196 reads (21%) | called by muse, mutect2, varscan2
- LIPC | c.88+4644G>A | Intron (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
- LRP1 | c.67+14C>T | Intron (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
